MMRF case MMRF_2043 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/29c86960-4692-4fd3-b626-20595ec64e0a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.6 years (25,790 days); ISS stage: III; Days to last known disease status: 928 days (2.5 years); Days to last follow up: 928 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 202 days; Days to treatment end: 254 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 8.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 248 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 97.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 15.9 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 15.4 g/dL; Glucose 4.84 mmol/L.
- Day 81 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.449 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.95 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 6.88 mmol/L.
- Day 194 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.957 g/L; Immunoglobulin M 0.528 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 257 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Hemoglobin 8.49 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.21 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.06 mmol/L.
- Day 344: Hemoglobin 8.93 mmol/L; Leukocytes 4.14 ×10⁹/L; Absolute Neutrophil 2.17 ×10⁹/L; Platelets 163 ×10⁹/L.
- Day 435 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Hemoglobin 9.67 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.37 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.67 mmol/L.
- Day 630 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.998 mg/dL.
- Day 805 (ECOG 0): M Protein 0 g/dL; Hemoglobin 9.55 mmol/L; Leukocytes 5.21 ×10⁹/L; Absolute Neutrophil 2.84 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 928 (ECOG 0): M Protein 0 g/dL; Hemoglobin 10 mmol/L; Leukocytes 5.18 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -3: Weight: 80 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2043_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2043_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
